CTSP case CTSP-AD28 — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef939e8e-8f38-43c8-8a7f-9908500632b3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1984; Vital status: Dead; Days to death: 21 days; Year of death: 2011; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 27.1 years (9,898 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 21 days; Best overall response: No Response; Ann Arbor extranodal involvement: No; Double hit lymphoma: No; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 183 cm; BMI: 17.6.

Biospecimens (1 sample)
- Sample DLBCL11319-sample: Sample type: Tumor; Tissue type: Tumor.
